Gene-level copy-number profile of tumor specimen ALCH-ABY0-TTP1-A from ALCHEMIST case ALCH-ABY0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.2 years (27,476 days).
Specimen ALCH-ABY0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8d305621-d469-4d75-a5b0-56504e929040.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABY0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/168c10da-123a-4523-9daa-5acea4fc4bf5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 654; copy number 1: 18,963; copy number 2: 34,320; copy number 3: 3,639; copy number 4: 1,217; copy number 5: 87; copy number 6: 17; copy number 9: 10.

Homozygous deletions (total copy number 0; autosomes only): 347 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,526,597, 4 genes: PLCH2, AL139246.1, AL139246.4, PANK4.
- chr2:128,236,716–128,350,927, 2 genes: HS6ST1, Y_RNA.
- chr2:232,343,116–232,550,573, 17 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG, TIGD1, MIR5001.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr3:128,462,439–128,472,317, 2 genes: DNAJB8, DNAJB8-AS1.
- chr4:3,244,369–3,271,738, 1 gene: MSANTD1.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:710,355–784,729, 2 genes: ZDHHC11B, BRD9P2.
- chr5:10,971,836–14,871,778, 26 genes (within-gene range 0–1): CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637.
- chr5:20,304,045–20,305,448, 1 gene (within-gene range 0–2): AC094103.1.
- chr5:20,606,710–30,365,684, 90 genes (broad region; genes not listed).
- chr5:176,810,519–176,899,346, 2 genes: UNC5A, HK3.
- chr5:180,601,506–180,649,624, 1 gene: FLT4.
- chr7:1,428,465–1,504,389, 4 genes: MICALL2, AC102953.1, AC102953.2, INTS1.
- chr7:66,511,556–66,592,397, 5 genes (within-gene range 0–2): AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1.
- chr7:73,735,038–73,738,867, 2 genes: ABHD11-AS1, ABHD11.
- chr7:102,264,706–102,321,711, 3 genes (within-gene range 0–1): AC005088.1, SH2B2, MIR4285.
- chr8:22,544,986–22,798,616, 13 genes (within-gene range 0–1): SORBS3, AC037459.4, AC037459.3, PDLIM2, AC037459.1, C8orf58, CCAR2, AC037459.2, BIN3, AC105046.1, EGR3, AC055854.1, AC105046.2.
- chr9:21,178,589–22,455,740, 48 genes: IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr10:19,598,247–19,728,550, 3 genes (within-gene range 0–2): U3, RNA5SP303, AL157895.1.
- chr10:19,747,823–19,748,621, 1 gene (within-gene range 0–2): MTND2P16.
- chr12:124,324,415–124,567,589, 9 genes (within-gene range 0–1): NCOR2, MIR6880, AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:40,835,808–40,956,512, 9 genes: SPINT1-AS1, SPINT1, RHOV, AC025166.1, VPS18, AC020661.1, DLL4, ISCA1P4, CHAC1.
- chr15:77,568,970–77,993,057, 13 genes (within-gene range 0–1): AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1, CSPG4P13, AC104758.2, AC104758.3, RN7SL214P, COMMD4P1, AC104758.4, ADAMTS7P3.
- chr15:96,325,938–96,405,235, 6 genes (within-gene range 0–1): NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5.
- chr16:2,968,024–3,027,755, 12 genes (within-gene range 0–2): PKMYT1, PAQR4, AC004233.3, LINC00514, AC004233.1, AC004233.4, AC004233.2, CLDN9, CLDN6, TNFRSF12A, HCFC1R1, THOC6.
- chr17:1,934,677–2,063,241, 12 genes (within-gene range 0–2): RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1.
- chr17:2,072,823–2,072,956, 1 gene (within-gene range 0–2): AC090617.9.
- chr17:21,284,672–21,419,870, 2 genes: MAP2K3, KCNJ12.
- chr17:38,530,031–38,605,952, 2 genes: SRCIN1, AC006449.1.
- chr17:39,603,536–39,670,475, 6 genes: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT.
- chr18:35,082,009–35,082,242, 1 gene (within-gene range 0–2): AC015967.2.
- chr18:78,795,612–78,928,494, 4 genes: AC044873.1, AC091027.2, AC091027.1, AC091027.3.
- chr18:79,395,856–79,951,657, 17 genes: NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2.
- chr21:44,300,051–44,339,402, 4 genes (within-gene range 0–2): PFKL, AP001062.3, CFAP410, AP001062.1.
- chr22:19,667,023–19,783,593, 5 genes (within-gene range 0–1): AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.
- chr22:29,705,256–29,767,011, 5 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA.
- chr22:45,920,366–45,977,162, 1 gene: WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 114 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 9: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr1:89,295–133,723, 1 gene, copy number 5 (within-gene range 2–5): AL627309.1.
- chr5:58,198–438,291, 14 genes, copy number 5 (within-gene range 4–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR.
- chr5:1,317,752–1,708,868, 14 genes, copy number 6: CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277.
- chr14:18,333,726–18,419,273, 3 genes, copy number 5–6: CR383658.1, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,569,097, 1 gene, copy number 6 (within-gene range 3–6): ANKRD26P1.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5–9 (within-gene range 2–9): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:14,371,115–18,760,320, 65 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,447. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
